CGCI case HTMCP-03-06-02379 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/67137e9d-c86c-4be0-bb0d-264faf6ad7b7

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 338 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: N0; AJCC clinical M: M0; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 338 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 9 days; Days to treatment end: 74 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 116 days; Days to treatment end: 130 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2400; Treatment outcome: Partial Response; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: -10 days; Disease response: With Tumor.
- Days to follow up: 0 days; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 210 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 210 days.
- Days to follow up: 338 days; Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Negative.

Other clinical attributes
- Day 0: Weight: 60 kg; Height: 161 cm; BMI: 23.1; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Postmenopausal; Pregnant at diagnosis: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02379-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02379-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02379-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 10; Total pregnancy count: 10; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form, Treatment, Radiation therapy info: Brachytherapy type: HDR.
- Follow-up form, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event site other: ENDOMETRIUM & PARAMETRIUM; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes.
- Treatments, Treatment 2: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Paclitaxel + Cisplatin.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02379-01A-01D-10409:
- % tumour top: 70
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02379-10A-01D-10409:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet_20191105.xlsx, for sample HTMCP-03-06-02379-01A-02D-10409:
- % tumour top: 70
- % tumour bottom: 60
